Gene-level copy-number profile of tumor specimen ALCH-B3EU-TTP1-A from ALCHEMIST case ALCH-B3EU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.6 years (27,235 days).
Specimen ALCH-B3EU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8739e8a9-27d0-4328-a403-01a0b2b286c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3EU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/f4f4ceba-1b62-4458-bd80-5ed97f055878

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,966; copy number 2: 53,402; copy number 3: 1,814; copy number 4: 706; copy number 5: 1; copy number 13: 1; copy number 17: 1; copy number 26: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,478,775–41,484,683, 1 gene: EDN2.
- chr2:131,492,813–131,521,573, 1 gene: SMPD4BP.
- chr3:53,797,764–53,846,419, 2 genes (within-gene range 0–2): AC012467.1, CHDH.
- chr5:177,438,503–177,456,286, 2 genes (within-gene range 0–2): PRR7-AS1, PRR7.
- chr7:5,475,804–5,479,811, 1 gene (within-gene range 0–2): AC092171.2.
- chr7:76,968,197–77,004,308, 3 genes (within-gene range 0–4): FDPSP7, AC114737.1, DTX2P1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr13:98,435,405–98,435,840, 1 gene (within-gene range 0–2): FARP1-AS1.
- chr15:77,976,042–77,993,057, 1 gene (within-gene range 0–2): ADAMTS7P3.
- chr15:77,993,405–77,995,289, 1 gene (within-gene range 0–2): AC104758.1.
- chr20:64,102,394–64,242,253, 1 gene (within-gene range 0–2): MYT1.
- chr22:36,487,190–36,507,043, 1 gene: FOXRED2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,851,551, 2 genes, copy number 5–17: NCF1, GTF2IRD2.
- chr21:43,107,942–43,168,646, 1 gene, copy number 26 (within-gene range 2–26): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 26: AP001631.1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 13 (within-gene range 3–13): LINC00313.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
